Somatic mutation profile of tumor specimen MMRF_1621_1_BM_CD138pos (aliquot MMRF_1621_1_BM_CD138pos_T1_KHS5U_K14082) from MMRF case MMRF_1621, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.2 years (22,004 days).
Specimen MMRF_1621_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13d4dced-86ac-494a-8153-f42b5e09e466.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1621_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1621_1_PB_Whole_C1_KHS5U_K14072; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1304b015-e36d-49ce-adf8-2569a03a9a0f

The open-access MAF lists 92 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 24, Intron 19, Silent 10, 5'Flank 3, 3'Flank 3, Splice Site 2, Splice Region 1, RNA 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 66/126 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACCS | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 155/244 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as rs372547657; called by muse, mutect2, varscan2
- ADAMTS12 | c.3958G>A p.G1320R | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs772207271, COSV61263569; called by muse, mutect2, varscan2
- CLK3 | c.749G>A p.R250Q (on ENST00000395066 / NM_001130028.1; = p.R102Q on NM_003992.4) | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs796316616, COSV61413639; called by muse, mutect2, varscan2
- DNAJC10 | c.688A>G p.M230V | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs369375869; called by muse, mutect2, varscan2
- HSD17B11 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1396340487; called by muse, mutect2, varscan2
- IGLV3-1 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); catalogued as rs189772470; called by muse, mutect2, varscan2
- IGLV3-1 | c.312T>G p.Y104* | Nonsense Mutation (SNP) | VAF 72/136 reads (53%) | catalogued as rs554055200; called by muse, mutect2, varscan2
- LTB | c.208+8C>T | Splice Region (SNP) | VAF 144/297 reads (48%) | catalogued as rs752684862, COSV59865114; called by muse, mutect2, varscan2
- MFHAS1 | c.2284G>A p.A762T | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.043); catalogued as rs1362759825; called by muse, mutect2, varscan2
- MKI67 | c.3658G>T p.A1220S | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.6); catalogued as rs1271540308; called by muse, mutect2, varscan2
- OR2A12 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV101283173; called by muse, mutect2, varscan2
- TFAP2B | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.57); catalogued as COSV53824920; called by muse, mutect2
- TIE1 | c.2551G>A p.G851S | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs931782166; called by muse, mutect2, varscan2
- TMEM132D | c.3157G>A p.V1053I | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750913130, COSV67160883; called by muse, mutect2, varscan2
- TNIK | c.2211C>A p.S737R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs769915449; called by muse, mutect2, varscan2
- ZNF546 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.631); catalogued as rs370350034; called by muse, mutect2
- CDH12 | c.2080A>C p.K694Q | Missense Mutation (SNP) | VAF 194/290 reads (67%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- IGHV2-70D | c.268A>C p.I90L | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.2); called by muse, varscan2
- IGKV1-8 | c.167A>C p.Y56S | Missense Mutation (SNP) | VAF 99/214 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ISL1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MBD4 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 175/269 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PQBP1 | c.292+2dup p.X98_splice | Splice Site (INS) | VAF 54/76 reads (71%) | called by mutect2, pindel, varscan2
- SCN8A | c.2306T>A p.F769Y | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SERPINB7 | c.1130T>C p.V377A | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2
- SLC6A1 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SNRK | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- SWAP70 | c.1523T>C p.L508S | Missense Mutation (SNP) | VAF 122/198 reads (62%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, varscan2
- SWAP70 | c.1554+2T>A p.X518_splice | Splice Site (SNP) | VAF 110/188 reads (59%) | called by muse, varscan2
- TUBB2A | c.142A>C p.N48H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- WNT5A | c.914G>T p.S305I | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA12 | c.1038A>G p.L346= (on ENST00000272895 / NM_173076.3; = p.L28= on NM_015657.3) | Silent (SNP) | VAF 41/79 reads (52%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.2088G>T p.A696= | Silent (SNP) | VAF 85/265 reads (32%) | catalogued as rs747221059, COSV55273297; called by muse, mutect2, varscan2
- HKDC1 | c.762G>A p.R254= | Silent (SNP) | VAF 83/206 reads (40%) | catalogued as rs971347322; called by muse, mutect2, varscan2
- IGHV2-70D | c.324T>A p.P108= | Silent (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- KCNB1 | c.1710C>T p.A570= | Silent (SNP) | VAF 57/102 reads (56%) | catalogued as COSV65569865; called by muse, mutect2, varscan2
- PCDH7 | c.1890T>C p.A630= | Silent (SNP) | VAF 59/149 reads (40%) | called by muse, mutect2, varscan2
- PNMA2 | c.405C>T p.P135= | Silent (SNP) | VAF 34/40 reads (85%) | catalogued as rs765056245; called by muse, mutect2, varscan2
- PRDX1 | c.228T>C p.A76= | Silent (SNP) | VAF 26/78 reads (33%) | called by mutect2, varscan2
- SETMAR | c.162T>G p.T54= | Silent (SNP) | VAF 65/137 reads (47%) | called by muse, mutect2, varscan2
- USH2A | c.6699G>A p.E2233= | Silent (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- ACER3 | c.*5892C>T | 3'UTR (SNP) | VAF 29/106 reads (27%) | called by muse, mutect2, varscan2
- ACMSD | c.*39T>A | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- ACTL10 | c.-335C>T | 5'UTR (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- ADAM12 | c.*1711C>A | 3'UTR (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- ADAMTS17 | c.*1272A>T | 3'UTR (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- AFAP1 | c.-3+459C>T | Intron (SNP) | VAF 111/230 reads (48%) | called by muse, mutect2, varscan2
- AKAP11 | c.*402G>A | 3'UTR (SNP) | VAF 7/27 reads (26%) | catalogued as rs1316219190; called by muse, mutect2, varscan2
- BCL7A | chr12:122021380 C>A | 5'Flank (SNP) | VAF 58/129 reads (45%) | called by muse, mutect2, varscan2
- BMP6 | c.*296_*306del | 3'UTR (DEL) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- CFAP43 | c.1443-408G>T | Intron (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- CTSH | c.124-395C>A | Intron (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- DCSTAMP | c.*356C>G | 3'UTR (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- DUOXA1 | chr15:45117647 C>A | 3'Flank (SNP) | VAF 121/249 reads (49%) | catalogued as COSV50993340; called by muse, mutect2, varscan2
- EIF2AK2 | c.*3453T>C | 3'UTR (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- F2RL2 | c.*1375dup | 3'UTR (INS) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- FAM133A | c.*270dup | 3'UTR (INS) | VAF 20/25 reads (80%) | catalogued as rs769947198; called by mutect2, varscan2
- GAB1 | chr4:143472013 A>G | 3'Flank (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- GADD45B | c.146+11C>A | Intron (SNP) | VAF 10/36 reads (28%) | called by muse, varscan2
- GADD45B | c.146+12C>T | Intron (SNP) | VAF 10/34 reads (29%) | called by muse, varscan2
- GADD45B | c.146+13C>A | Intron (SNP) | VAF 10/34 reads (29%) | called by muse, varscan2
- GAK | c.3508+321G>A | Intron (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2
- GCC2-AS1 | chr2:108534522 A>T | 5'Flank (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- GEN1 | c.*953C>G | 3'UTR (SNP) | VAF 57/112 reads (51%) | called by muse, mutect2, varscan2
- GRIK4 | c.907-4728A>G | Intron (SNP) | VAF 9/118 reads (8%) | called by muse, mutect2
- HDAC4 | c.2855-68G>A | Intron (SNP) | VAF 38/103 reads (37%) | catalogued as rs773541160; called by muse, mutect2, varscan2
- HOXD3 | chr2:176174501 del ACAGTGTGTTACCGCAGGAGTATCT | 3'Flank (DEL) | VAF 15/148 reads (10%) | called by mutect2, pindel
- HTR1F | c.*687C>G | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- HTR1F | c.*1281C>G | 3'UTR (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- IL5RA | c.994+2124dup | Intron (INS) | VAF 33/93 reads (35%) | called by mutect2, pindel, varscan2
- INA | c.*1224G>A | 3'UTR (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- LTB | c.163-154C>T | Intron (SNP) | VAF 93/209 reads (44%) | catalogued as rs543196679; called by muse, mutect2, varscan2
- N4BP3 | c.*2232A>T | 3'UTR (SNP) | VAF 155/237 reads (65%) | called by muse, mutect2, varscan2
- NAA30 | c.*1528T>G | 3'UTR (SNP) | VAF 60/124 reads (48%) | called by muse, mutect2
- NFKBIZ | chr3:101849264 C>T | 5'Flank (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- NKX2-3 | c.*104dup | 3'UTR (INS) | VAF 9/32 reads (28%) | catalogued as rs896689451; called by mutect2, varscan2
- OAS3 | c.*1608A>G | 3'UTR (SNP) | VAF 64/136 reads (47%) | called by muse, mutect2
- PALLD | c.1502-8766del | Intron (DEL) | VAF 48/102 reads (47%) | catalogued as rs890865851; called by mutect2, varscan2
- PARP11 | c.*646C>A | 3'UTR (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- PGM3 | c.1540-447A>G | Intron (SNP) | VAF 100/219 reads (46%) | called by muse, mutect2, varscan2
- RBM46 | c.1403-184A>T | Intron (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- RIC1 | c.*1932G>A | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- RSPO3 | c.98-48dup | Intron (INS) | VAF 18/40 reads (45%) | catalogued as rs1176256483; called by mutect2, varscan2
- SLC17A1 | c.*2+92C>T | Intron (SNP) | VAF 251/574 reads (44%) | called by muse, mutect2, varscan2
- SLC6A15 | c.756+2781A>G | Intron (SNP) | VAF 33/78 reads (42%) | catalogued as COSV57031673; called by muse, mutect2, varscan2
- SSBL3P1 | n.464G>T | RNA (SNP) | VAF 19/112 reads (17%) | called by muse, mutect2, varscan2
- ST3GAL2 | c.-1003-436C>T | Intron (SNP) | VAF 74/157 reads (47%) | catalogued as rs528464437; called by muse, mutect2, varscan2
- TMEM106B | c.*1715A>C | 3'UTR (SNP) | VAF 27/114 reads (24%) | catalogued as COSV67543440; called by muse, mutect2, varscan2
- TTC14 | c.*501A>G | 3'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- UBAC2 | c.31+383T>G | Intron (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- ZFAND5 | c.*3710C>T | 3'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2
- ZFP91 | c.*331T>G | 3'UTR (SNP) | VAF 37/116 reads (32%) | catalogued as rs1277997625; called by muse, mutect2, varscan2
